CCDI case PBBNZJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c1b0ecdc-e7e1-4605-be06-764a0e071103

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,712 days).

Biospecimens (3 samples)
- Sample 0DELJ1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DELJV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DELKA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
